Surgical pathology report (de-identified scan), TCGA case TCGA-24-1546, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1546-01A (Primary Tumor).

[page 1 of 4]
FINAL

* Converted Case * This report may not match the original report format

Physician(s):

DIAGNOSIS:

OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED
(SEE DESCRIPTION)

SOFT TISSUE, PAROVARIAN, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY - PAPILLARY SEROUS ADENOCARCINOMA

FALLOPIAN TUBES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITIES

OMENTUM, BIOPSY (FS1) - PAPILLARY SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED

OMENTUM, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED

SOFT TISSUE, POSTERIOR CUL-DE-SAC, BIOPSY (FS2)
- PAPILLARY SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED

LIVER, BIOPSY - SOFT TISSUE CONTAINING PAPILLARY SEROUS ADENOCARCINOMA

UTERUS, SEROSA, ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED, METASTATIC

VAGINA, POSTERIOR, ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED, METASTATIC

UTERUS, ENDOMETRIUM, ABDOMINAL HYSTERECTOMY - INACTIVE

UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITIES

UTERUS, CERVIX, ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITIES

ENTEROCELE SAC, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED, METASTATIC

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[page 2 of 4]
[REDACTED]

Intraoperative Consultation:

FS1: Omentum, biopsy - "Metastatic adenocarcinoma, favor mullerian [REDACTED]"

FS2: Peritoneum, posterior cul-de-sac, biopsy
- "Metastatic adenocarcinoma, favor mullerian primary," [REDACTED]

Microscopic Description and Comment:

There is widespread, poorly differentiated papillary serous adenocarcinoma in this case. In many areas, the tumor grows as small solid nests, although there is also considerable epithelial tufting and micropapillary formation. The great bulk of tumor is extra-ovarian with extensive replacement of the omentum and involvement of the posterior cul-de-sac, enterocele sac, and peri-hepatic soft tissue. The latter biopsy, submitted as "liver biopsy" consists only of soft tissue; no liver parenchyma is included in the sample. The ovaries are small and of normal configuration. There are multiple small serosal tumor nodules and involvement of parovarian soft tissue. Each ovary contains a focus of cortical involvement measuring 4 mm and 7 mm (left and right ovaries respectively) in maximum dimension. By [REDACTED] criteria, this degree of cortical involvement (any nodule exceeding 5 mm in diameter) would be considered consistent with an ovarian primary.

Foci of metastatic papillary serous adenocarcinoma are identified on the uterine serosa. There is a small focus of tumor in the posterior para-vaginal soft tissue. The endometrium is inactive. There are no significant histopathologic abnormalities in the myometrium or cervix. [REDACTED]

History:

The patient is a [REDACTED] with ascites and pelvic mass. Operative procedure and findings: Examination under anesthesia, exploratory laparotomy, omentectomy, debulking, total abdominal hysterectomy and bilateral salpingo-oophorectomy. [REDACTED]

Specimen(s) Received:

A: FS1- OMENTUM
B: X1- OMENTUM
C: FS2- PERITONEUM, POSTERIOR CUL-DE-SAC
D: OMENTUM
E: LIVER NODULE
F: UTERUS, CERVIX, BSO
G: INTRACELE SAC

Gross Description:

The specimens are received in seven containers of formalin, each labelled with the patient's name. The first container is additionally labeled 'FS1,' and contains three irregularly shaped adipose tissue fragments measuring approximately 1.5 x 1.0 x 0.5 cm in aggregate. The entire specimen is submitted as FS1. Jar 0.

The second container is additionally labeled "X1, omentum" and contains three irregularly shaped yellowish-grey tissue fragments measuring approximately 1.7 x 1.5 x 1.0 cm in aggregate. The entire specimen is submitted as A. [REDACTED]

The third container is additionally labeled "#2 posterior cul-de-sac, FS2." It contains a single irregularly shaped greyish-tan tissue fragment measuring approximately 0.5 x 0.4 x [REDACTED]

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

0.3 cm. The entire specimen is submitted as FS2.

The fourth container is additionally labeled "#3 omentum," and contains two irregularly shaped omental cakes measuring 12 x 4 x 3.5 and 2.3 x 1.0 x 0.5 cm. Serial sectioning show diffuse replacement and infiltration of the adipose tissue by greyish-white and soft rubbery tumor mass. Three representative sections are submitted as B1 through B3.

The fifth container is additionally labeled "liver nodule," and contains two irregularly shaped hemorrhagic to greyish-tan tissue fragments measuring approximately 3 x 2.5 x 1 cm in aggregate. One of the fragments is focally covered by some greyish-white gelatinous-appearing material. Representative sections are submitted as C1 and C2.

The sixth container is additionally labeled "uterus, cervix, bilateral salpingo-oophorectomy and cul-de-sac." It contains a uterus with attached cervix, vaginal tissue, and bilateral ovaries and fallopian tubes. The uterus measures 6 cm superoinferiorly, 3.5 cm mediolaterally, 2.5 cm anteroposteriorly, and weighs approximately 50 grams. The peritoneal reflection is greyish-pink and irregularly nodular anteriorly and posteriorly. The endometrial cavity measures 4 x 1.2 cm and is of a uniform pinkish-red color. The myometrium is grossly unremarkable and has an average thickness of approximately 1.1 cm. The cervix measures 4 x 2.5 x 2.5 cm. The mucosal surface is greyish-white and grossly unremarkable. There is a slit-like os, which measures approximately 1.0 cm in diameter. The endocervical canal is grossly unremarkable. The attached anterior and posterior vaginal tissue measures approximately 1.5 x 1.5 x 0.5 and 6.0 x 5.0 x 0.6 cm respectively. The surface of the vaginal mucosa is pinkish-white, slightly wrinkled, but otherwise unremarkable. The left fallopian tube measures 4.5 cm in length and approximately 0.5 cm in diameter excluding the fimbriated end. It shows a purplish-grey, smooth serosal surface superiorly but diffusely adhered to the ovary inferiorly. The left ovary measures 3.0 x 2.0 x 0.7 cm. The external surface is greyish-pink and bosselated. The parenchyma shows two irregularly shaped greyish-white firm areas with the largest one measuring approximately 2.0 cm in greatest dimension. There is another irregularly shaped greyish-white firm mass identified adjacent to the proximal portion of left fallopian tube measuring approximately 2.2 x 1.0 x 1.5 cm. The mass does not appear to have penetrated into the lumen of fallopian tube but rather encases it externally. The right ovary measures 2.5 x 1.5 x 1.0 cm. It shows a greyish-white, slightly wrinkled, external surface. The parenchyma shows a mottling of yellowish-grey alternating with some greyish-white firm areas at the periphery. The right fallopian tube measures 5.5 cm in length and with an average diameter of 0.5 cm excluding the fimbriated end. The serosal surface is purplish-grey and smooth with patchy areas of subserosal hemorrhage. In addition there are two irregularly shaped separate fragments of vaginal tissue found in the container that measure 2.5 x 2.0 x 0.7 cm in aggregate volume. Labeled D1 - anterior uterine wall; D2 - anterior lower uterine segment containing subserosal nodules; D3 - posterior uterine wall; D4 - posterior lower uterine segment containing subserosal nodules; D5 - section of anterior cervix with attached vaginal tissue; D6 AND D7 - sections of posterior cervix with attached vaginal tissue; D8 and D9 - sections of left ovary; D10 - section of the largest mass as proximal left fallopian tube; D11 and D12 - sections of fallopian tube with relationship to the peritubal mass; D13 - sections of the right ovary; D14 - sections of the right fallopian tube.

The seventh container is additionally labeled "#6 intracoele sac," and contains an irregularly shaped greyish-pink tissue fragment measuring approximately 9 x 4.5 x 0.5 cm. The surface of the specimen is irregularly nodular and shows focal areas of mottling yellow discoloration. Representative sections are submitted as E1 and E2.

Source: NCI Genomic Data Commons file d72aa82a-aefb-40fb-9790-b69b7d8d97ae (TCGA-24-1546.D6EEC9A6-7BFD-40E2-891E-0A3CD7759ACE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).